Gene-level copy-number profile of tumor specimen TCGA-EJ-5504-01A from TCGA case TCGA-EJ-5504, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 65.9 years (24,072 days).
Specimen TCGA-EJ-5504-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.267120ee-7aab-4a7c-9d84-1ce7dfbcdef8.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EJ-5504-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 352 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3bef7669-b787-4455-a8cb-bd246fe50194

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,893; copy number 1: 15,245; copy number 2: 41,887; copy number 3: 106; copy number 5: 115; copy number 6: 25.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EJ-5504-01A-01D-1574-01): tumor purity 0.35, ploidy 1.86, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 512 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:159,587,826–159,599,227, 2 genes: APCS, OR10J6P.
- chr2:49,878,623–49,888,986, 2 genes: RPL7P13, SNORA75.
- chr2:50,324,643–50,345,598, 1 gene: AC068725.1.
- chr5:180,967,189–181,006,727, 4 genes (within-gene range 0–2): AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr6:31,394,289–31,478,936, 7 genes: AL645933.2, MICA, AL645933.3, Y_RNA, LINC01149, AL645933.1, HCP5.
- chr6:84,421,028–117,573,571, 447 genes (within-gene range 0–1) (broad region; genes not listed).
- chr6:117,457,734–117,457,838, 1 gene: RNU6-253P.
- chr11:37,938,601–38,014,141, 2 genes: LINC02760, AC103798.1.
- chr11:113,797,874–116,500,630, 45 genes (within-gene range 0–1): USP28, AP003170.3, AP003170.1, RNU6-1107P, HTR3B, HTR3A, ZBTB16, AP002755.1, AP002518.2, NNMT, AP002518.1, C11orf71, RBM7, AP002373.1, REXO2, AP002373.2, NXPE2P1, AC020549.3, NXPE1, AC020549.1, NXPE4, AC020549.2, NXPE2, AP003179.1, CADM1, AP000465.1, AP000462.3, AP000462.1, AP000462.2, AP003174.2, AP003174.3, RPL12P46, AP003174.1, AP000997.1, AP000997.2, AP000997.3, AP000997.4, LINC02698, AP002991.1, AP002991.2, LINC00900, LINC02703, AP000797.2, AP000797.1, LINC02151.
- chr12:55,522,593–55,523,417, 1 gene: OR6C64P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 140 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 6 (within-gene range 1–6): AC244205.1.
- chr2:88,857,161–89,117,844, 24 genes, copy number 6: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17.
- chr14:105,546,610–106,360,324, 115 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 15,239. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
